Somatic mutation profile of cancer-model specimen HCM-CSHL-0438-C18-85B (3D Organoid, passage 10; aliquot HCM-CSHL-0438-C18-85B-01D-A82H-36), derived from the primary tumor of HCMI case HCM-CSHL-0438-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-CSHL-0438-C18-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9026762-8ccb-4d8d-ad7d-abd4256290ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0438-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0438-C18-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84a21dbc-5e19-4884-9367-0aea0987fb75

The open-access MAF lists 1,450 somatic variants for this specimen: 1,084 protein-altering or splice-affecting, 323 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 783, Silent 323, Frame Shift Del 196, Nonsense Mutation 50, Frame Shift Ins 36, Intron 27, Splice Site 7, In Frame Del 6, Splice Region 6, 5'UTR 5, 3'Flank 5, 3'UTR 3.

Variants (750 of 1,450; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.11700del p.K3900Nfs*8 | Frame Shift Del (DEL) | VAF 147/376 reads (39%) | catalogued as rs1553421626; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ARSL | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 105/105 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs122460153, CM131741, CM950098; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/286 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CACNA1A | c.41del p.G14Efs*74 | Frame Shift Del (DEL) | VAF 318/934 reads (34%) | catalogued as rs1555797179; ClinVar: pathogenic; called by pindel, varscan2
- CASK | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 178/179 reads (99%) | catalogued as rs387906704, CM118654, COSV59376402; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFTR | c.2052del p.K684Nfs*38 | Frame Shift Del (DEL) | VAF 74/198 reads (37%) | catalogued as rs121908746; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FBN1 | c.6322C>T p.R2108C | Missense Mutation (SNP) | VAF 118/239 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1246984265, CD157732, COSV57316763; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- FBXW7 | c.1559A>T p.D520V (on ENST00000281708 / NM_001349798.2; = p.D440V on NM_018315.5) | Missense Mutation (SNP) | VAF 226/433 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55913982, COSV55975767; called by muse, mutect2, varscan2
- FOXP2 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 57/201 reads (28%) | catalogued as rs121908378, CM051480, COSV100647565; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.8401C>T p.R2801* | Nonsense Mutation (SNP) | VAF 246/510 reads (48%) | catalogued as rs1555191203, CM138446, COSV56410607; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 74/76 reads (97%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 40/111 reads (36%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYH7 | c.4300C>T p.R1434C | Missense Mutation (SNP) | VAF 209/749 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs730880800, CM115853, COSV62517542; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 176/386 reads (46%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABL2 | c.2311A>G p.S771G (on ENST00000502732 / NM_007314.4; = p.S756G on NM_005158.5) | Missense Mutation (SNP) | VAF 285/571 reads (50%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1426450675, COSV61013249; called by muse, mutect2, varscan2
- ABLIM2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 132/285 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV56413081; called by muse, mutect2, varscan2
- AC013489.1 | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 134/303 reads (44%) | catalogued as COSV51554107; called by muse, mutect2, varscan2
- ACAN | c.7153C>T p.R2385W (on ENST00000560601 / NM_001369268.1; = p.R2309W on NM_001135.3) | Missense Mutation (SNP) | VAF 314/716 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1428837585; called by muse, mutect2
- ACAP3 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 272/593 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.649); catalogued as rs574253017; called by muse, mutect2, varscan2
- ACER2 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 198/422 reads (47%) | catalogued as COSV100575819; called by muse, mutect2, varscan2
- ACP7 | c.1118G>A p.C373Y | Missense Mutation (SNP) | VAF 170/359 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1415135745; called by muse, mutect2, varscan2
- ACSL6 | c.1981G>A p.D661N (on ENST00000379240; = p.D686N on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/205 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV99732713; called by muse, mutect2, varscan2
- ACTN2 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 236/487 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs752906680, COSV63975775, COSV63977364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAD2 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 287/630 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); catalogued as rs766436532; called by muse, mutect2, varscan2
- ADAMTS13 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 162/410 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1554790056, COSV100747142; called by muse, mutect2
- ADAMTS4 | c.2414C>T p.P805L | Missense Mutation (SNP) | VAF 248/549 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.965); catalogued as rs568445358; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1263G>A p.M421I | Missense Mutation (SNP) | VAF 231/486 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs945253912; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4522dup p.V1508Gfs*80 | Frame Shift Ins (INS) | VAF 253/642 reads (39%) | catalogued as rs777337513; called by mutect2, pindel, varscan2
- ADAMTSL3 | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99721086; called by muse, mutect2, varscan2
- ADCY8 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 205/471 reads (44%) | catalogued as COSV99651556; called by muse, mutect2, varscan2
- ADGRL3 | c.334C>T p.R112C (on ENST00000506720 / NM_001322402.2; = p.R44C on NM_015236.6) | Missense Mutation (SNP) | VAF 177/328 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767946394; called by muse, mutect2, varscan2
- AGBL2 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs754816884, COSV54091073; called by muse, mutect2, varscan2
- AGFG1 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 159/301 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as rs761100669, COSV59510354; called by muse, varscan2
- AGO4 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 121/264 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.528); catalogued as rs1205447580, COSV64616271; called by muse, varscan2
- AHCTF1 | c.3778C>T p.R1260* (on ENST00000366508; = p.R1234* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 96/242 reads (40%) | catalogued as rs1558223606, COSV58247045; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHCY | c.1069G>A p.V357M | Missense Mutation (SNP) | VAF 237/492 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.419); catalogued as rs745484709; called by muse, mutect2, varscan2
- AIFM3 | c.186del p.S63Afs*34 | Frame Shift Del (DEL) | VAF 305/736 reads (41%) | catalogued as rs1197894880; called by mutect2, pindel, varscan2
- AKAP8L | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 143/280 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1267121368, COSV101275695, COSV101275821; called by muse, mutect2, varscan2
- AKAP9 | c.3625G>A p.V1209I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs929172053; called by muse, mutect2, varscan2
- ALDH1B1 | c.1043T>C p.V348A | Missense Mutation (SNP) | VAF 264/506 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs764809001; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.3208C>T p.Q1070* | Nonsense Mutation (SNP) | VAF 276/605 reads (46%) | catalogued as COSV66563942; called by muse, mutect2, varscan2
- AMBN | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 226/478 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775535240, COSV59827164; called by muse, mutect2, varscan2
- ANGPTL2 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 247/503 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs778400951, COSV99402456; called by muse, mutect2, varscan2
- ANGPTL7 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 166/340 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as rs758868900; called by muse, mutect2, varscan2
- ANK2 | c.7964C>T p.S2655L | Missense Mutation (SNP) | VAF 205/425 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as rs373153154, COSV52147308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD24 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 399/839 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as rs1358148318; called by muse, mutect2, varscan2
- ANKRD29 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 83/320 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs372274223; called by muse, mutect2, varscan2
- ANKRD30B | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 126/261 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs779324265; called by muse, mutect2, varscan2
- ANKRD62 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 200/592 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs905911647, COSV58409888; called by muse, mutect2, varscan2
- ANKS1A | c.181del p.L61Sfs*13 | Frame Shift Del (DEL) | VAF 268/681 reads (39%) | catalogued as rs1201951499; called by mutect2, pindel, varscan2
- ANKUB1 | c.1288dup p.I430Nfs*6 | Frame Shift Ins (INS) | VAF 138/317 reads (44%) | catalogued as rs1314304040; called by mutect2, varscan2
- ANTXR1 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 210/390 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs370351341, COSV58009335; called by muse, mutect2, varscan2
- AP1G2 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 200/617 reads (32%) | catalogued as rs376016480; called by muse, mutect2, varscan2
- APC2 | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 299/619 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752529365; called by muse, mutect2, varscan2
- APLP1 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 245/553 reads (44%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs7249156; called by muse, mutect2, varscan2
- AQP2 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 341/690 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs763156762, COSV52230820; called by muse, mutect2, varscan2
- ARHGEF17 | c.2192A>G p.Y731C | Missense Mutation (SNP) | VAF 283/548 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1408296704; called by muse, mutect2, varscan2
- ARMH2 | c.136del p.I46Sfs*20 | Frame Shift Del (DEL) | VAF 168/346 reads (49%) | catalogued as rs965020534; called by mutect2, varscan2
- ASH2L | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 80/260 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.396); catalogued as rs1302863174; called by muse, varscan2
- ASXL1 | c.4172G>A p.S1391N | Missense Mutation (SNP) | VAF 282/588 reads (48%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.678); catalogued as COSV100038520; called by muse, mutect2, varscan2
- ATG16L2 | c.1789G>A p.V597M | Missense Mutation (SNP) | VAF 259/507 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1444911780, COSV58361422; called by muse, mutect2, varscan2
- ATP1A4 | c.148-1G>T p.X50_splice | Splice Site (SNP) | VAF 140/293 reads (48%) | catalogued as COSV100927651; called by muse, mutect2, varscan2
- ATP2A1 | c.2941G>A p.D981N | Missense Mutation (SNP) | VAF 151/392 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763414497; called by muse, mutect2, varscan2
- ATP2B4 | c.3577del p.Q1193Sfs*9 | Frame Shift Del (DEL) | VAF 192/486 reads (40%) | catalogued as COSV58175925; called by mutect2, pindel, varscan2
- ATP6V1B2 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 97/241 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV52353183; called by muse, mutect2, varscan2
- ATRNL1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 450/901 reads (50%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs782639550, COSV61814251; called by muse, mutect2, varscan2
- BAHCC1 | c.1754del p.G585Vfs*49 | Frame Shift Del (DEL) | VAF 311/820 reads (38%) | catalogued as COSV57031417; called by mutect2, pindel, varscan2
- BCL9L | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 328/708 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.662); catalogued as rs1200604418; called by muse, varscan2
- BICD1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 142/271 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0.119); catalogued as rs765998934; called by muse, mutect2, varscan2
- BICDL2 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 261/470 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV54158457; called by muse, mutect2, varscan2
- BNC1 | c.225del p.M76Cfs*14 | Frame Shift Del (DEL) | VAF 139/287 reads (48%) | catalogued as rs751941533; called by mutect2, varscan2
- BNIP1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs752048025; called by muse, mutect2, varscan2
- BRAT1 | c.1313A>G p.Q438R | Missense Mutation (SNP) | VAF 240/469 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs777754523; called by muse, varscan2
- BTBD17 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 381/776 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1409893467, COSV100945288; called by muse, mutect2, varscan2
- BTN2A2 | c.1138G>T p.G380W | Missense Mutation (SNP) | VAF 147/289 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61858077; called by muse, mutect2, varscan2
- C1orf68 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 223/459 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs553777962, COSV64224429; called by muse, mutect2, varscan2
- C3 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 197/449 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.212); catalogued as rs758391076, COSV55573642; called by muse, mutect2, varscan2
- C3orf20 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 353/676 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs151210868; called by muse, mutect2, varscan2
- C9orf43 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs200902357, COSV55912689; called by muse, mutect2, varscan2
- CACNA1C | c.4783C>T p.R1595W | Missense Mutation (SNP) | VAF 227/499 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs867596743, COSV100216598; called by muse, mutect2, varscan2
- CACNA1I | c.5740G>A p.V1914I | Missense Mutation (SNP) | VAF 172/350 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs752733821, COSV60804081; called by muse, mutect2, varscan2
- CACNA2D2 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 150/329 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs367932722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 106/200 reads (53%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC189 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 278/524 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as rs753229558; called by muse, mutect2
- CCDC25 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 131/297 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as rs768473604; called by muse, mutect2, varscan2
- CCDC85C | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 550/1131 reads (49%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.099); catalogued as COSV66549726; called by muse, mutect2, varscan2
- CCKBR | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 363/715 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58099194; called by muse, mutect2, varscan2
- CCL14 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 230/486 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs771441014; called by muse, mutect2, varscan2
- CD82 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 255/518 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs755265941; called by muse, mutect2, varscan2
- CD93 | c.943dup p.A315Gfs*34 | Frame Shift Ins (INS) | VAF 246/538 reads (46%) | catalogued as rs747115137; called by mutect2, varscan2
- CDC34 | c.147del p.N50Tfs*29 | Frame Shift Del (DEL) | VAF 222/438 reads (51%) | catalogued as rs769066610; called by mutect2, varscan2
- CDH1 | c.1666del p.V556* | Frame Shift Del (DEL) | VAF 194/478 reads (41%) | catalogued as COSV55733260; called by mutect2, pindel, varscan2
- CEACAM5 | c.1802dup p.D602Rfs*19 | Frame Shift Ins (INS) | VAF 113/292 reads (39%) | catalogued as rs782698410; called by mutect2, varscan2
- CEP170 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs34312127; called by muse, mutect2, varscan2
- CEP170B | c.4271G>A p.R1424Q (on ENST00000453495; = p.R1353Q on NM_015005.3) | Missense Mutation (SNP) | VAF 713/942 reads (76%) | SIFT tolerated (0.12); PolyPhen benign (0.3); catalogued as rs571111410, COSV99229822; called by muse, mutect2, varscan2
- CFAP251 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 196/427 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs375750046; called by muse, mutect2, varscan2
- CFAP43 | c.3920A>G p.Y1307C | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63855262; called by muse, mutect2, varscan2
- CFAP74 | c.2611C>A p.P871T | Missense Mutation (SNP) | VAF 179/336 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72210544; called by muse, mutect2, varscan2
- CHD8 | c.3544C>T p.R1182* (on ENST00000646647 / NM_001170629.2; = p.R903* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 155/491 reads (32%) | catalogued as rs747319027; called by muse, mutect2, varscan2
- CHPF | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 359/723 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368679810; called by muse, mutect2, varscan2
- CHRD | c.1212C>T p.D404= | Splice Region (SNP) | VAF 151/319 reads (47%) | catalogued as rs757550404, COSV52608921, COSV52611068; called by muse, mutect2, varscan2
- CHRNA4 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 195/488 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV100937248; called by muse, mutect2, varscan2
- CHST3 | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 354/723 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1244264696, COSV64150865; called by muse, mutect2, varscan2
- CNOT11 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 494/950 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.086); catalogued as rs1286293848; called by muse, mutect2, varscan2
- CNTNAP4 | c.79A>G p.N27D | Missense Mutation (SNP) | VAF 110/226 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1463795770; called by muse, mutect2, varscan2
- CNTNAP4 | c.486G>A p.W162* | Nonsense Mutation (SNP) | VAF 151/354 reads (43%) | catalogued as COSV56666710; called by muse, mutect2, varscan2
- CNTRL | c.1336del p.I446* | Frame Shift Del (DEL) | VAF 100/255 reads (39%) | catalogued as rs747099268; called by mutect2, varscan2
- COL24A1 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 169/348 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); catalogued as rs1427068654; called by muse, mutect2, varscan2
- COL7A1 | c.2887C>T p.R963C | Missense Mutation (SNP) | VAF 216/431 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs773083989, COSV60399006; called by muse, mutect2, varscan2
- COMMD5 | c.79del p.A27Pfs*14 | Frame Shift Del (DEL) | VAF 257/630 reads (41%) | catalogued as COSV59311043; called by mutect2, pindel, varscan2
- CORO1C | c.457A>G p.N153D | Missense Mutation (SNP) | VAF 114/214 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV54596376; called by muse, mutect2, varscan2
- CPAMD8 | c.4888C>T p.R1630W (on ENST00000651564; = p.R1583W on NM_015692.5) | Missense Mutation (SNP) | VAF 250/470 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs201395525; called by muse, mutect2, varscan2
- CPT1A | c.2155G>A p.G719S | Missense Mutation (SNP) | VAF 157/310 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs765825411; called by muse, mutect2, varscan2
- CRACD | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 136/303 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs773479718, COSV51717674; called by muse, mutect2, varscan2
- CRAT | c.495del p.K166Sfs*5 | Frame Shift Del (DEL) | VAF 169/366 reads (46%) | catalogued as rs772054700, COSV58879005; called by mutect2, varscan2
- CREBBP | c.4728+1G>A p.X1576_splice | Splice Site (SNP) | VAF 107/224 reads (48%) | catalogued as CS065532, COSV52122377; called by muse, mutect2, varscan2
- CRYGC | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 121/263 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as rs372921291; called by muse, mutect2, varscan2
- CSMD2 | c.2653G>A p.V885M | Missense Mutation (SNP) | VAF 216/489 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs141404520; called by muse, mutect2, varscan2
- CSPG4 | c.5173G>A p.V1725M | Missense Mutation (SNP) | VAF 237/509 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs764884311; called by muse, mutect2, varscan2
- CSRNP3 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 205/452 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs563868095, COSV58782255; called by muse, varscan2
- CTU1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 463/895 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs868588627; called by muse, mutect2, varscan2
- CUL1 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 163/399 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.151); catalogued as rs748809924; called by muse, mutect2, varscan2
- CUL3 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 73/230 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.185); catalogued as rs972626651, COSV52369309; called by muse, varscan2
- CXCL14 | c.148G>A p.D50N (on ENST00000337225; = p.D38N on NM_004887.5) | Missense Mutation (SNP) | VAF 45/400 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.147); catalogued as rs781637591; called by muse, mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | catalogued as rs745836350; called by mutect2, varscan2
- CYP1B1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 414/907 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs1204570375; called by muse, mutect2, varscan2
- CYP2S1 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 197/466 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs762153062, COSV59507469; called by muse, mutect2, varscan2
- DCLRE1A | c.1038dup p.R347Tfs*11 | Frame Shift Ins (INS) | VAF 123/354 reads (35%) | catalogued as rs1405598603; called by mutect2, pindel, varscan2
- DDN | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 357/702 reads (51%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.013); catalogued as rs781700633; called by muse, mutect2, varscan2
- DDX56 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 181/333 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs141049623, COSV51837378; called by muse, mutect2, varscan2
- DDX60L | c.3338del p.L1113Cfs*38 | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | catalogued as rs757771764; called by mutect2, varscan2
- DENND5A | c.1807G>A p.V603I | Missense Mutation (SNP) | VAF 150/311 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.688); catalogued as rs1343747838; called by muse, mutect2, varscan2
- DGKZ | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 300/580 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as rs533730571; called by muse, mutect2, varscan2
- DHCR7 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 190/368 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs565893436, CM010205, COSV62794728; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- DHX37 | c.3124C>T p.R1042C | Missense Mutation (SNP) | VAF 135/305 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs774923441; called by muse, mutect2, varscan2
- DKK2 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 242/510 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs758193352, COSV53395161, COSV53397132; called by muse, mutect2, varscan2
- DLC1 | c.2942C>T p.P981L (on ENST00000276297 / NM_001348081.2; = p.P544L on NM_006094.5) | Missense Mutation (SNP) | VAF 182/378 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs781401048; called by muse, varscan2
- DLGAP1 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 419/690 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as rs200970393, COSV59800019; called by muse, mutect2, varscan2
- DMPK | c.161-7C>A | Splice Region (SNP) | VAF 298/605 reads (49%) | catalogued as COSV52176751; called by mutect2, varscan2
- DMTN | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 247/535 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1391106819, COSV99741782; called by muse, mutect2, varscan2
- DNAH5 | c.4760A>T p.D1587V | Missense Mutation (SNP) | VAF 141/313 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs191586822; called by muse, mutect2, varscan2
- DNAH8 | c.3518A>G p.N1173S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs1313070138; called by muse, mutect2, varscan2
- DNAJB2 | c.523C>G p.Q175E | Missense Mutation (SNP) | VAF 208/412 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs377437714, COSV100339060; called by muse, mutect2, varscan2
- DOT1L | c.3214C>T p.R1072C | Missense Mutation (SNP) | VAF 446/944 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs769094667; called by muse, mutect2, varscan2
- DRC1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 319/708 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.059); catalogued as COSV99985624; called by muse, mutect2, varscan2
- DRD2 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 138/298 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.309); catalogued as rs752633977, COSV60757519; called by muse, varscan2
- DSCAML1 | c.1739G>A p.R580Q (on ENST00000321322; = p.R520Q on NM_020693.4) | Missense Mutation (SNP) | VAF 207/451 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as rs777504529, COSV100357415, COSV58380343; called by muse, mutect2, varscan2
- DSPP | c.2500G>A p.D834N | Missense Mutation (SNP) | VAF 154/351 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.953); catalogued as rs977451306, COSV56807689; called by mutect2, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 98/221 reads (44%) | catalogued as rs755197346; called by mutect2, varscan2
- DYTN | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 178/367 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs551795566; called by muse, mutect2, varscan2
- EBF1 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 139/301 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs550230265; called by muse, mutect2, varscan2
- EBNA1BP2 | c.162G>T p.K54N | Missense Mutation (SNP) | VAF 137/291 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV99355856; called by muse, mutect2, varscan2
- ECEL1 | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 283/565 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs370872631; called by muse, mutect2, varscan2
- EFL1 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 133/305 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.513); catalogued as rs1478789281, COSV51609409, COSV51610556; called by muse, mutect2, varscan2
- EFR3B | c.2060G>A p.R687H | Missense Mutation (SNP) | VAF 165/345 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs199969836; called by muse, mutect2, varscan2
- EHMT2 | c.2159C>T p.T720M | Missense Mutation (SNP) | VAF 350/727 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747277461; called by muse, mutect2, varscan2
- EIF2D | c.1669G>A p.G557S | Missense Mutation (SNP) | VAF 104/220 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs546078025; called by muse, mutect2, varscan2
- EIF4EBP2 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 181/420 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs750591080, COSV100947032; called by muse, mutect2
- ENTPD2 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 309/667 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1327416064; called by muse, mutect2, varscan2
- EPHB3 | c.1972C>T p.R658* | Nonsense Mutation (SNP) | VAF 177/386 reads (46%) | catalogued as rs780703655; called by muse, mutect2, varscan2
- ERN1 | c.1331T>C p.M444T | Missense Mutation (SNP) | VAF 239/504 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs773517950; called by muse, mutect2, varscan2
- ESRP1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 164/362 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746769438; called by muse, varscan2
- EYS | c.8401G>A p.G2801R (on ENST00000370621 / NM_001292009.1; = p.G2780R on NM_001142800.2) | Missense Mutation (SNP) | VAF 129/247 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.229); catalogued as COSV65512347; called by muse, mutect2, varscan2
- FADS2 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 51/374 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs199630600, COSV53902241; called by muse, mutect2, varscan2
- FAM151A | c.351del p.T118Lfs*43 | Frame Shift Del (DEL) | VAF 242/593 reads (41%) | catalogued as rs749953492; called by mutect2, pindel, varscan2
- FAM171A1 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 129/269 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747672439; called by muse, mutect2, varscan2
- FAM83D | c.1543del p.H515Tfs*6 | Frame Shift Del (DEL) | VAF 211/464 reads (45%) | catalogued as rs754952124; called by mutect2, varscan2
- FARP2 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 152/320 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as rs375677515; called by muse, mutect2, varscan2
- FAT1 | c.10276G>A p.V3426M | Missense Mutation (SNP) | VAF 204/429 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs772835024; called by muse, varscan2
- FBXL7 | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 259/535 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1356248686, COSV61641264; called by muse, mutect2, varscan2
- FBXW7 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 207/468 reads (44%) | catalogued as rs781123562, COSV55916781; called by muse, mutect2, varscan2
- FCAR | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 280/605 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs771484287; called by muse, mutect2, varscan2
- FCGR2C | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 138/325 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs755093735; called by muse, mutect2, varscan2
- FGD1 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 374/375 reads (100%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as rs1309206982; called by muse, mutect2, varscan2
- FGF4 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 402/832 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1158890592, COSV51449444; called by muse, varscan2
- FGFR1 | c.1655C>T p.T552M (on ENST00000447712 / NM_023110.3; = p.T550M on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760702592, COSV58347371; called by muse, mutect2, varscan2
- FILIP1 | c.113del p.K38Rfs*22 | Frame Shift Del (DEL) | VAF 189/451 reads (42%) | catalogued as COSV99384757; called by mutect2, pindel, varscan2
- FLT1 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 173/566 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1161996687, COSV56724342; called by muse, mutect2, varscan2
- FN1 | c.3082C>T p.R1028* | Nonsense Mutation (SNP) | VAF 259/522 reads (50%) | catalogued as COSV60564371; called by muse, mutect2, varscan2
- FNDC11 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 337/671 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs373437672; called by muse, mutect2, varscan2
- FOXL2 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 434/830 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57729024, COSV57729085; called by muse, mutect2, varscan2
- FOXN4 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 161/338 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as rs1258683192; called by muse, mutect2, varscan2
- FURIN | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 273/594 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as rs757314750, COSV99184646; called by muse, mutect2, varscan2
- FUT5 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 44/448 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781164561; called by muse, mutect2
- FZD10 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 344/674 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777832754, COSV57473252; called by muse, mutect2, varscan2
- GAMT | c.64del p.A22Rfs*20 | Frame Shift Del (DEL) | VAF 365/764 reads (48%) | catalogued as rs1569009071; called by mutect2, varscan2
- GAS7 | c.1152G>A p.M384I (on ENST00000432992 / NM_201433.2; = p.M244I on NM_003644.3) | Missense Mutation (SNP) | VAF 176/364 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV60436425; called by muse, mutect2, varscan2
- GBF1 | c.2885G>A p.C962Y (on ENST00000369983 / NM_001377137.1; = p.C961Y on NM_004193.3) | Missense Mutation (SNP) | VAF 126/285 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1261673685; called by muse, mutect2, varscan2
- GBX1 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 350/675 reads (52%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs775141734; called by muse, mutect2, varscan2
- GFM2 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 97/218 reads (44%) | catalogued as rs766229932, COSV57190165; called by muse, mutect2, varscan2
- GJA10 | c.1523C>A p.P508H | Missense Mutation (SNP) | VAF 118/280 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV101005361; called by muse, mutect2, varscan2
- GKN1 | c.481del p.Y161Tfs*38 | Frame Shift Del (DEL) | VAF 121/314 reads (39%) | catalogued as rs759880395; called by mutect2, pindel, varscan2
- GMPPB | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 281/600 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as rs748809549, COSV57537655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPATCH8 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 197/445 reads (44%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100132637; called by muse, mutect2, varscan2
- GPR173 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 359/364 reads (99%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV100212272; called by muse, mutect2, varscan2
- GPR62 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 412/798 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1277478633; called by muse, mutect2, varscan2
- GRID2IP | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 474/1040 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as rs759492755; called by muse, mutect2, varscan2
- GRIN2D | c.3739G>A p.A1247T | Missense Mutation (SNP) | VAF 92/163 reads (56%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1034596120; called by muse, varscan2
- GRIN3B | c.635A>G p.D212G | Missense Mutation (SNP) | VAF 465/971 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as rs1220962392; called by muse, mutect2, varscan2
- GSTCD | c.1351G>A p.G451S (on ENST00000360505 / NM_001031720.3; = p.G364S on NM_024751.3) | Missense Mutation (SNP) | VAF 125/263 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755349586; called by muse, mutect2, varscan2
- GZF1 | c.1282A>G p.T428A | Missense Mutation (SNP) | VAF 393/765 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1311569117; called by muse, mutect2, varscan2
- HACD1 | c.611A>T p.N204I | Missense Mutation (SNP) | VAF 68/135 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV63516404; called by muse, mutect2, varscan2
- HAGH | c.252C>T p.V84= | Splice Region (SNP) | VAF 182/380 reads (48%) | catalogued as rs372218473; called by muse, mutect2, varscan2
- HCN4 | c.3130C>T p.R1044W | Missense Mutation (SNP) | VAF 270/559 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs553950644; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDGFL1 | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 320/756 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1389488879, COSV57751074; called by mutect2, varscan2
- HECTD4 | c.12778G>A p.V4260M | Missense Mutation (SNP) | VAF 364/720 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.464); catalogued as rs755661535; called by muse, varscan2
- HECTD4 | c.9718dup p.A3240Gfs*5 | Frame Shift Ins (INS) | VAF 286/568 reads (50%) | catalogued as rs754540615; called by mutect2, varscan2
- HEG1 | c.3733C>T p.P1245S | Missense Mutation (SNP) | VAF 185/386 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as rs1454122493; called by muse, mutect2, varscan2
- HEG1 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 63/563 reads (11%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs759177087; called by muse, mutect2, varscan2
- HEPACAM | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 119/253 reads (47%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.497); catalogued as rs149093986; ClinVar: likely benign; called by muse, mutect2, varscan2
- HEXA | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 193/430 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.065); catalogued as rs766988109; called by muse, mutect2, varscan2
- HIC2 | c.899del p.G300Afs*17 | Frame Shift Del (DEL) | VAF 345/864 reads (40%) | catalogued as rs1388756225, COSV68041693; called by mutect2, pindel, varscan2
- HIP1R | c.3073C>T p.R1025W | Missense Mutation (SNP) | VAF 339/686 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs149673932; called by muse, mutect2, varscan2
- HLA-A | c.103T>C p.S35P | Missense Mutation (SNP) | VAF 334/597 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV65144323; called by muse, varscan2
- HNRNPA1L2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 128/473 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.223); catalogued as rs780540859; called by muse, mutect2, varscan2
- HOXC9 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 360/715 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.453); catalogued as rs1485767057; called by muse, mutect2, varscan2
- HOXD13 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 218/490 reads (44%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1166185321, COSV66832816; called by mutect2, varscan2
- HS3ST4 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 240/427 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.695); catalogued as rs1404429317; called by muse, mutect2, varscan2
- HUNK | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 89/187 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.469); catalogued as rs748171279, COSV54227411; called by muse, mutect2, varscan2
- ICAM4 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 273/581 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs779599159, COSV99320941; called by muse, mutect2, varscan2
- IDO1 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 110/219 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs373557196; called by muse, varscan2
- IFT122 | c.1462C>A p.L488I (on ENST00000348417 / NM_052989.3; = p.L429I on NM_018262.4) | Missense Mutation (SNP) | VAF 142/316 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.401); catalogued as COSV56203312; called by muse, mutect2, varscan2
- IFT172 | c.4598C>T p.T1533M | Missense Mutation (SNP) | VAF 165/412 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs202181028, COSV53136918; called by muse, mutect2, varscan2
- IGHM | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 311/1220 reads (25%) | SIFT deleterious (0.01); catalogued as rs1398324382; called by muse, mutect2, varscan2
- IGHV3-53 | c.105del p.S36Pfs*2 | Frame Shift Del (DEL) | VAF 96/233 reads (41%) | catalogued as rs782011069; called by mutect2, varscan2
- IGLV3-16 | c.147del p.K49Nfs*17 | Frame Shift Del (DEL) | VAF 90/390 reads (23%) | catalogued as rs746629447; called by pindel, varscan2
- IL17RE | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 97/219 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.777); catalogued as rs1387516644; called by muse, mutect2, varscan2
- IL6ST | c.1587del p.V530* | Frame Shift Del (DEL) | VAF 101/254 reads (40%) | catalogued as rs776023104; called by mutect2, pindel, varscan2
- INPP4A | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 330/718 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.308); catalogued as rs372688727, COSV99303199; called by muse, mutect2, varscan2
- IQCE | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 197/376 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs367624205; called by muse, varscan2
- ISM1 | c.579del p.R194Gfs*82 | Frame Shift Del (DEL) | VAF 252/539 reads (47%) | catalogued as rs762230866, COSV99339624; called by mutect2, varscan2
- ITGA5 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 380/804 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs756815283, COSV53216035; called by mutect2, varscan2
- ITGA7 | c.1775G>A p.R592H (on ENST00000555728; = p.R548H on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 237/474 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs746596659, COSV57696580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGA7 | c.1528G>A p.A510T (on ENST00000555728; = p.A466T on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 189/409 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as rs61733964; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGB4 | c.3673C>T p.R1225C | Missense Mutation (SNP) | VAF 231/441 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99563138; called by muse, mutect2, varscan2
- ITIH5 | c.1715A>G p.H572R | Missense Mutation (SNP) | VAF 226/487 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.733); catalogued as COSV53660090; called by muse, mutect2, varscan2
- ITPKA | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 178/383 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV53026452; called by muse, mutect2, varscan2
- ITPR3 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 210/450 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560642079; called by muse, mutect2
- ITSN1 | c.2534C>T p.T845M | Missense Mutation (SNP) | VAF 113/255 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as rs200510636; called by muse, mutect2, varscan2
- JCAD | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 240/473 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs747299480; called by muse, mutect2, varscan2
- JUNB | c.415T>G p.F139V | Missense Mutation (SNP) | VAF 400/831 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56878064; called by muse, mutect2, varscan2
- KCNA1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 308/641 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV66838775; called by muse, mutect2, varscan2
- KCNC2 | c.47del p.G16Afs*32 | Frame Shift Del (DEL) | VAF 298/737 reads (40%) | catalogued as COSV54368827; called by mutect2, pindel, varscan2
- KCNJ11 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 347/686 reads (51%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.687); catalogued as rs766658650, CM1211851; called by muse, mutect2, varscan2
- KDM2B | c.2633G>A p.R878H | Missense Mutation (SNP) | VAF 272/602 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.68); catalogued as rs782296633; called by muse, varscan2
- KIF13A | c.5117C>A p.P1706H | Missense Mutation (SNP) | VAF 238/456 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.188); catalogued as rs1235384224; called by muse, mutect2, varscan2
- KIF16B | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 140/330 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1478305353, COSV61705892; called by muse, mutect2
- KIF26A | c.5185G>A p.G1729R | Missense Mutation (SNP) | VAF 1246/1703 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1566867487; called by muse, mutect2, varscan2
- KIF2C | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 173/373 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1283621357, COSV64765639; called by muse, mutect2, varscan2
- KIF5B | c.2822G>A p.R941H | Missense Mutation (SNP) | VAF 115/231 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1194314131; called by muse, mutect2, varscan2
- KIR2DL4 | c.829G>A p.A277T (on ENST00000396284; = p.A238T on NM_001080772.2) | Missense Mutation (SNP) | VAF 170/615 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs1480801249, COSV58492657; called by muse, mutect2
- KIRREL2 | c.496C>A p.L166M | Missense Mutation (SNP) | VAF 174/332 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.266); catalogued as COSV52876209; called by muse, varscan2
- KLHL10 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 257/544 reads (47%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.446); catalogued as rs781939002, COSV53174197; called by muse, mutect2, varscan2
- KLHL14 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 98/393 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs747697000, COSV63832245; called by muse, mutect2, varscan2
- KLRB1 | c.518del p.L173* | Frame Shift Del (DEL) | VAF 33/63 reads (52%) | catalogued as rs1162765987; called by mutect2, pindel, varscan2
- KMT2A | c.10871C>A p.A3624E | Missense Mutation (SNP) | VAF 124/301 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); catalogued as rs1204869035, COSV63285073; called by muse, mutect2, varscan2
- KRIT1 | c.143del p.K48Rfs*17 | Frame Shift Del (DEL) | VAF 72/146 reads (49%) | catalogued as rs776245507; called by mutect2, varscan2
- KRT33B | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 184/430 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs750809007, COSV52440042; called by muse, mutect2, varscan2
- LAMA1 | c.8659G>A p.A2887T | Missense Mutation (SNP) | VAF 359/585 reads (61%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs747612750, COSV67531820; called by muse, mutect2, varscan2
- LAMA5 | c.9696dup p.E3233Rfs*7 | Frame Shift Ins (INS) | VAF 317/938 reads (34%) | catalogued as rs1193133918; called by pindel, varscan2
- LAMA5 | c.9101del p.G3034Afs*73 | Frame Shift Del (DEL) | VAF 335/820 reads (41%) | catalogued as rs780673654; called by mutect2, pindel, varscan2
- LAMP1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 195/400 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.759); catalogued as rs767683537, COSV58148576; called by muse, mutect2, varscan2
- LANCL2 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 179/435 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs759096269, COSV54648593; called by muse, mutect2, varscan2
- LANCL3 | c.192del p.L65Ffs*129 | Frame Shift Del (DEL) | VAF 348/520 reads (67%) | catalogued as rs782221297; called by mutect2, pindel, varscan2
- LARP1 | c.898G>C p.A300P (on ENST00000518297 / NM_033551.3; = p.A223P on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 204/487 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1168661265; called by mutect2, varscan2
- LARP4 | c.2132G>A p.R711H | Missense Mutation (SNP) | VAF 162/325 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs576259847, COSV53319898; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 82/229 reads (36%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LCA5L | c.1004del p.N335Tfs*38 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as COSV55744803; called by pindel, varscan2
- LDB3 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 302/632 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs1324305691, COSV53946946; called by muse, mutect2, varscan2
- LIPG | c.887A>G p.Q296R | Missense Mutation (SNP) | VAF 210/671 reads (31%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.999); catalogued as rs1476014725; called by muse, mutect2, varscan2
- LMTK2 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 136/304 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.746); catalogued as rs751573329, COSV51989516, COSV51992815; called by muse, mutect2, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 172/360 reads (48%) | catalogued as rs748712732; called by mutect2, varscan2
- LOXHD1 | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 403/665 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.43); catalogued as rs199771475; called by muse, mutect2, varscan2
- LRCH3 | c.1647G>A p.S549= | Splice Region (SNP) | VAF 114/249 reads (46%) | catalogued as rs778617574, COSV58389749; called by muse, mutect2, varscan2
- LRP1 | c.5978G>A p.R1993Q | Missense Mutation (SNP) | VAF 183/410 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs948848252; called by muse, mutect2, varscan2
- LRP1 | c.11202del p.T3735Qfs*48 | Frame Shift Del (DEL) | VAF 236/498 reads (47%) | catalogued as COSV54518902; called by mutect2, pindel, varscan2
- LRP1 | c.12013G>A p.A4005T | Missense Mutation (SNP) | VAF 176/326 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs779077274; called by muse, mutect2, varscan2
- LRRC14 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 272/599 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); catalogued as rs754279276; called by muse, varscan2
- LRRK2 | c.2129del p.N710Mfs*2 | Frame Shift Del (DEL) | VAF 104/218 reads (48%) | catalogued as COSV54153441; called by mutect2, varscan2
- LRRK2 | c.4915del p.R1639Gfs*15 | Frame Shift Del (DEL) | VAF 88/112 reads (79%) | catalogued as rs756089224; called by mutect2, varscan2
- LSG1 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 101/232 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs377238265; called by muse, mutect2, varscan2
- MAD1L1 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 210/500 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.241); catalogued as rs371823704; called by muse, mutect2, varscan2
- MAF | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 124/206 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs754099605; called by muse, varscan2
- MAP1S | c.1910G>A p.R637H | Missense Mutation (SNP) | VAF 373/726 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs774928303, COSV60722011; called by muse, mutect2, varscan2
- MAP3K1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 308/697 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs1490594459; called by muse, mutect2, varscan2
- MAP4K3 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 41/141 reads (29%) | catalogued as rs1229077607; called by muse, varscan2
- MAP7D1 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 212/473 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs772737835, COSV100294568; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2573C>T p.P858L | Missense Mutation (SNP) | VAF 327/674 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as rs758172491; called by muse, mutect2, varscan2
- MAPKBP1 | c.4316C>T p.S1439L (on ENST00000456763 / NM_001128608.2; = p.S1433L on NM_014994.3) | Missense Mutation (SNP) | VAF 267/547 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs767527456; called by muse, mutect2, varscan2
- MBD6 | c.1997del p.P666Hfs*9 | Frame Shift Del (DEL) | VAF 92/189 reads (49%) | catalogued as COSV63073363; called by mutect2, varscan2
- MCM3AP | c.1265G>C p.S422T | Missense Mutation (SNP) | VAF 155/316 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV99386443; called by muse, mutect2, varscan2
- METAP2 | c.152-1G>A p.X51_splice | Splice Site (SNP) | VAF 105/214 reads (49%) | catalogued as COSV54151122; called by muse, mutect2, varscan2
- MGA | c.3744del p.E1249Rfs*42 | Frame Shift Del (DEL) | VAF 151/394 reads (38%) | catalogued as rs1193719928; called by mutect2, pindel, varscan2
- MIA3 | c.4711C>T p.R1571W | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as rs764893679, COSV60515995; called by muse, mutect2, varscan2
- MICAL3 | c.3031G>A p.E1011K | Missense Mutation (SNP) | VAF 158/365 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as rs376048597; called by muse, varscan2
- MICALL2 | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 243/557 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as rs756397828; called by muse, mutect2, varscan2
- MMP21 | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 379/773 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1330698369, COSV64289225; called by muse, mutect2, varscan2
- MORC2 | c.2942G>A p.R981H (on ENST00000397641 / NM_001303256.3; = p.R919H on NM_014941.3) | Missense Mutation (SNP) | VAF 195/457 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs901120411, COSV53199173; called by muse, mutect2, varscan2
- MORC2 | c.1823G>A p.R608H (on ENST00000397641 / NM_001303256.3; = p.R546H on NM_014941.3) | Missense Mutation (SNP) | VAF 163/340 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs781443418, COSV53199396; called by muse, mutect2, varscan2
- MORC3 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 99/207 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs758552820, COSV68203755; called by muse, mutect2, varscan2
- MPRIP | c.2416C>T p.R806W | Missense Mutation (SNP) | VAF 46/438 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1304001801; called by muse, mutect2, varscan2
- MRGBP | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 203/426 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1418246725; called by muse, mutect2, varscan2
- MRGPRX1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 225/453 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.868); catalogued as rs750486969, COSV57105964; called by muse, mutect2, varscan2
- MROH2A | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 231/511 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.257); catalogued as rs1162940902, COSV101082265; called by muse, mutect2, varscan2
- MRPL45 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 215/447 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs754342790; called by muse, mutect2, varscan2
- MSH2 | c.1003del p.T335Pfs*22 | Frame Shift Del (DEL) | VAF 217/533 reads (41%) | catalogued as CM011421; called by mutect2, pindel, varscan2
- MSH6 | c.3851C>T p.T1284M | Missense Mutation (SNP) | VAF 119/301 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs63750836, CM994622, COSV52277844; ClinVar: likely benign / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MTIF3 | c.477G>T p.K159N | Missense Mutation (SNP) | VAF 110/199 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100820204; called by muse, mutect2, varscan2
- MTOR | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 312/624 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs149221273; called by muse, mutect2, varscan2
- MUC16 | c.15256C>T p.R5086C | Missense Mutation (SNP) | VAF 153/310 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.265); catalogued as rs751244335, COSV67481460; called by muse, mutect2, varscan2
- MUC16 | c.948G>T p.E316D | Missense Mutation (SNP) | VAF 198/395 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV67471841; called by muse, mutect2, varscan2
- MYADM | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 286/632 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.448); catalogued as rs754778239, COSV61240884; called by muse, mutect2, varscan2
- MYH10 | c.5311G>A p.A1771T | Missense Mutation (SNP) | VAF 160/347 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs780429629; called by muse, mutect2, varscan2
- MYH14 | c.4823G>A p.R1608Q | Missense Mutation (SNP) | VAF 188/440 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs368076336; called by muse, mutect2, varscan2
- MYH6 | c.2716C>T p.R906C | Missense Mutation (SNP) | VAF 271/416 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs143928061, COSV62448810; called by muse, mutect2, varscan2
- MYL9 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 240/481 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as rs762174189; called by muse, mutect2, varscan2
- MYO18B | c.1496G>A p.S499N | Missense Mutation (SNP) | VAF 137/332 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs1221481657; called by muse, mutect2, varscan2
- MYO1B | c.2146C>T p.R716W | Missense Mutation (SNP) | VAF 194/412 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs539821767; called by muse, mutect2, varscan2
- MYO1F | c.2798G>A p.G933E | Missense Mutation (SNP) | VAF 195/484 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs201645601; called by muse, mutect2, varscan2
- MYO7A | c.5851G>A p.D1951N | Missense Mutation (SNP) | VAF 139/325 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs767931313; called by muse, mutect2
- NCL | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 173/350 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs758874312; called by muse, mutect2, varscan2
- NCOR2 | c.4172G>A p.R1391Q | Missense Mutation (SNP) | VAF 489/984 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1374909069; called by muse, mutect2, varscan2
- NFAM1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 130/322 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs140355227; called by muse, mutect2, varscan2
- NIPA2 | c.101del p.G34Afs*11 | Frame Shift Del (DEL) | VAF 99/272 reads (36%) | catalogued as rs111948120; called by mutect2, pindel, varscan2
- NKAIN2 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 244/491 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.165); catalogued as rs771967079; called by muse, mutect2, varscan2
- NKX2-8 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 293/953 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs780834818, COSV51873703; called by muse, mutect2, varscan2
- NOP56 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 16/485 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs922862787, COSV100250087; called by muse, mutect2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 79/228 reads (35%) | catalogued as rs1282346576; called by mutect2, pindel, varscan2
- NOTCH1 | c.4238G>A p.R1413H | Missense Mutation (SNP) | VAF 443/914 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs371068504; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH3 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 311/646 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs768965053, CM159172; called by muse, mutect2, varscan2
- NOTUM | c.704dup p.T236Hfs*12 | Frame Shift Ins (INS) | VAF 200/509 reads (39%) | catalogued as rs778719752; called by mutect2, pindel, varscan2
- NOX4 | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 169/365 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1444041385, COSV54467672; called by muse, mutect2, varscan2
- NR0B1 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 400/402 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV66764182; called by muse, mutect2, varscan2
- NTN1 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 308/671 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs954612636; called by muse, mutect2, varscan2
- NTN4 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 209/478 reads (44%) | catalogued as COSV59216968; called by muse, mutect2, varscan2
- OR2A5 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 242/480 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV68738603; called by muse, mutect2, varscan2
- OR2W3 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 233/480 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1295817530, COSV100831913; called by muse, mutect2, varscan2
- OR7G2 | c.384dup p.A129Cfs*14 | Frame Shift Ins (INS) | VAF 230/594 reads (39%) | catalogued as rs750339447; called by mutect2, pindel, varscan2
- OR8H1 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 194/447 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs1369006802, COSV57293417; called by muse, mutect2, varscan2
- OSBP2 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 246/517 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as rs372468624; called by muse, mutect2, varscan2
- OSGIN2 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 148/339 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs201554027, COSV52412274; called by muse, mutect2, varscan2
- OTOGL | c.1528G>A p.V510M (on ENST00000547103; = p.V501M on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.399); catalogued as rs747153629; called by muse, varscan2
- OXTR | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 208/422 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as rs762376033; called by muse, mutect2, varscan2
- PADI1 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 224/489 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as rs146693033; called by muse, mutect2, varscan2
- PAPPA2 | c.5055dup p.S1686Qfs*2 | Frame Shift Ins (INS) | VAF 92/207 reads (44%) | catalogued as rs747970462; called by mutect2, varscan2
- PAX5 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 291/630 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs1313118042, COSV63905600; called by muse, mutect2, varscan2
- PCDHA6 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 266/619 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.581); catalogued as rs373766273; called by muse, mutect2, varscan2
- PCDHA8 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 312/712 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.23); catalogued as COSV65337680, COSV65339512; called by muse, mutect2, varscan2
- PCDHA9 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 339/709 reads (48%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.009); catalogued as COSV99061505; called by muse, mutect2, varscan2
- PCDHB1 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 182/394 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1476926821, COSV60630188; called by muse, mutect2, varscan2
- PCDHB10 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 325/772 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1554284221, COSV53382385, COSV99503922; called by muse, mutect2, varscan2
- PCDHB5 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 171/402 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.106); catalogued as COSV50648885; called by muse, mutect2, varscan2
- PCDHGA4 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 248/482 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.503); catalogued as rs1228836363, COSV53968641; called by muse, mutect2, varscan2
- PCDHGB6 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 253/515 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); catalogued as COSV53967265; called by muse, mutect2, varscan2
- PDCD11 | c.4814C>T p.A1605V | Missense Mutation (SNP) | VAF 235/533 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as rs142228884; called by muse, mutect2, varscan2
- PDE1C | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 97/222 reads (44%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs760282457, COSV58513096; called by muse, mutect2, varscan2
- PDE6B | c.2114G>A p.R705Q | Missense Mutation (SNP) | VAF 151/328 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs200397909; called by muse, mutect2, varscan2
- PDGFC | c.946G>A p.G316S | Missense Mutation (SNP) | VAF 149/343 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs1455196232, COSV99924811, COSV99926064; called by muse, mutect2
- PDPR | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 122/573 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as rs369705156, COSV55348645, COSV55355973; called by muse, mutect2, varscan2
- PDS5A | c.2153+1G>A p.X718_splice | Splice Site (SNP) | VAF 53/114 reads (46%) | catalogued as COSV57830966; called by muse, mutect2, varscan2
- PDZD2 | c.5528A>G p.K1843R | Missense Mutation (SNP) | VAF 229/484 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1415881019, COSV56850143, COSV56851600; called by muse, mutect2, varscan2
- PELI3 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 278/567 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs773826652, COSV57856591; called by muse, mutect2, varscan2
- PER1 | c.2527C>T p.R843C | Missense Mutation (SNP) | VAF 407/834 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1363977334; called by muse, mutect2, varscan2
- PER1 | c.2320C>T p.R774C | Missense Mutation (SNP) | VAF 361/722 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373940863; called by muse, mutect2, varscan2
- PGAP6 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 393/803 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs143724021; called by muse, mutect2, varscan2
- PGPEP1L | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 243/462 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs778101933; called by muse, mutect2, varscan2
- PGR | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 242/515 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as rs11571151; called by muse, mutect2, varscan2
- PHYKPL | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 188/386 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs774564514, COSV57424072, COSV57427668; called by muse, mutect2, varscan2
- PKD1 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 289/775 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs1407462213; called by muse, mutect2, varscan2
- PKLR | c.479C>A p.P160Q | Missense Mutation (SNP) | VAF 253/534 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61360368, COSV61361066; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 129/281 reads (46%) | catalogued as rs745860467; called by mutect2, varscan2
- PLEC | c.9212C>T p.T3071M (on ENST00000322810 / NM_201380.4; = p.T2961M on NM_000445.5) | Missense Mutation (SNP) | VAF 300/577 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs368122904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHA7 | c.2893C>T p.R965* | Nonsense Mutation (SNP) | VAF 227/483 reads (47%) | catalogued as rs781159901, COSV100261923; called by muse, mutect2, varscan2
- PLEKHA7 | c.2405del p.F802Sfs*21 | Frame Shift Del (DEL) | VAF 146/300 reads (49%) | catalogued as rs1333390805, COSV63043367; called by mutect2, varscan2
- PLEKHH3 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 389/791 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs147643829; called by muse, mutect2, varscan2
- PLOD3 | c.1882C>T p.R628W | Missense Mutation (SNP) | VAF 257/522 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1034818885; called by muse, varscan2
- PLXNA1 | c.1982G>A p.C661Y | Missense Mutation (SNP) | VAF 16/438 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99303682; called by muse, mutect2
- PLXND1 | c.1555G>A p.V519M | Missense Mutation (SNP) | VAF 221/456 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs146955703; called by muse, mutect2, varscan2
- PLXND1 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 466/975 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs920158012; called by muse, mutect2, varscan2
- POLR3B | c.3320C>T p.P1107L | Missense Mutation (SNP) | VAF 114/231 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1486970206, COSV57284583; called by muse, mutect2, varscan2
- POMGNT2 | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 299/653 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs774025495, COSV60953727; called by muse, mutect2, varscan2
- PON1 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 185/453 reads (41%) | catalogued as COSV55934247; called by muse, mutect2, varscan2
- PON1 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs987766326, COSV55931497; called by muse, mutect2, varscan2
- PPP1R12A | c.1523C>T p.T508I | Missense Mutation (SNP) | VAF 90/222 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.702); catalogued as rs1442740645; called by muse, mutect2, varscan2
- PPP1R12C | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 235/487 reads (48%) | SIFT tolerated (0.78); PolyPhen benign (0.106); catalogued as rs748794982, COSV54736518; called by muse, mutect2, varscan2
- PPP1R27 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 318/648 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs369174976; called by muse, mutect2, varscan2
- PPP2R5A | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 300/567 reads (53%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1558135638; called by muse, mutect2, varscan2
- PPP2R5D | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 251/513 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751831580, COSV57839201; called by muse, mutect2, varscan2
- PRKAR2B | c.101A>G p.Q34R | Missense Mutation (SNP) | VAF 383/818 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs752054562; called by muse, mutect2, varscan2
- PRMT3 | c.561-1G>T p.X187_splice | Splice Site (SNP) | VAF 122/252 reads (48%) | catalogued as COSV58178153; called by muse, mutect2, varscan2
- PROSER2 | c.472C>A p.L158I | Missense Mutation (SNP) | VAF 279/677 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99508810; called by muse, mutect2, varscan2
- PRRC2A | c.3454C>T p.R1152C | Missense Mutation (SNP) | VAF 519/1006 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs142106114, COSV65689317; called by muse, mutect2, varscan2
- PRRT3 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 253/497 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.246); catalogued as COSV99926271; called by muse, mutect2, varscan2
- PRSS12 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 197/365 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); catalogued as rs143623699, COSV56606716; called by muse, mutect2, varscan2
- PSG2 | c.427T>C p.Y143H | Missense Mutation (SNP) | VAF 96/211 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs774584260, COSV101290493; called by muse, mutect2
- PSMA7 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 30/611 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.076); catalogued as rs1330486115; called by muse, mutect2
- PSMC3 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 200/446 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs895209304, COSV100099307; called by muse, mutect2, varscan2
- PTPRK | c.2721del p.D908Ifs*13 (on ENST00000368215 / NM_001291984.2; = p.D909Ifs*13 on NM_002844.4) | Frame Shift Del (DEL) | VAF 54/166 reads (33%) | catalogued as rs763877925; called by mutect2, pindel, varscan2
- PTPRS | c.1828C>T p.R610W | Missense Mutation (SNP) | VAF 282/594 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs1237159914, COSV53613755; called by muse, mutect2, varscan2
- PYGM | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 202/412 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.035); catalogued as rs139645637; called by muse, mutect2, varscan2
- RASGRF1 | c.2804del p.P935Qfs*11 | Frame Shift Del (DEL) | VAF 107/282 reads (38%) | catalogued as rs1567482049; called by mutect2, pindel, varscan2
- RASGRF1 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 211/401 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1234815073, COSV69181774; called by muse, mutect2, varscan2
- RBFOX2 | c.775C>T p.R259C (on ENST00000438146 / NM_001349995.2; = p.R189C on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53264194; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 58/141 reads (41%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 137/305 reads (45%) | catalogued as COSV56484832; called by mutect2, varscan2
- RCOR2 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 173/363 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1416494502; called by muse, varscan2
- REPIN1 | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 424/869 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.202); catalogued as COSV101262618; called by muse, mutect2, varscan2
- RGPD3 | c.2967del p.D990Tfs*52 | Frame Shift Del (DEL) | VAF 180/396 reads (45%) | catalogued as rs746667934; called by mutect2, varscan2
- RHBDD1 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 95/215 reads (44%) | catalogued as rs147605304; called by muse, mutect2, varscan2
- RHCG | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 250/551 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as rs760903375, COSV51517530; called by muse, mutect2, varscan2
- RHOU | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 17/488 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1319630683; called by muse, mutect2
- RNF165 | c.764del p.G255Efs*53 | Frame Shift Del (DEL) | VAF 310/496 reads (63%) | catalogued as COSV99491984; called by mutect2, varscan2
- RNF187 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 226/495 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1201648729, COSV59959895; called by muse, mutect2, varscan2
- RNF213 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 266/580 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as rs199976159; called by mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 269/590 reads (46%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- ROBO2 | c.1978C>T p.R660C | Missense Mutation (SNP) | VAF 134/275 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs912032432, COSV59939608; called by muse, mutect2, varscan2
- ROBO3 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 370/794 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1055336193; called by muse, mutect2, varscan2
- RTEL1 | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 238/497 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs777153220, COSV58900498; called by muse, mutect2, varscan2
- SALL3 | c.906del p.G303Afs*92 | Frame Shift Del (DEL) | VAF 74/151 reads (49%) | catalogued as rs1424702195; called by mutect2, pindel, varscan2
- SAMSN1 | c.208dup p.M70Nfs*14 | Frame Shift Ins (INS) | VAF 72/170 reads (42%) | catalogued as rs760167411; called by mutect2, varscan2
- SCAF1 | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 354/772 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.458); catalogued as rs755561525, COSV62183853; called by muse, mutect2, varscan2
- SCAF4 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 100/240 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs773592223, COSV54587881; called by muse, mutect2, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 118/308 reads (38%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SCN11A | c.4433G>A p.R1478Q | Missense Mutation (SNP) | VAF 216/491 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs758597298, COSV56577794; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 83/223 reads (37%) | catalogued as rs765136101; called by mutect2, pindel, varscan2
- SCN2B | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 110/243 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.066); catalogued as rs201460753; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN9A | c.1043G>A p.S348N | Missense Mutation (SNP) | VAF 162/361 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as COSV100310620; called by muse, mutect2, varscan2
- SCYGR5 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 302/641 reads (47%) | catalogued as rs995680635; called by muse, mutect2, varscan2
- SEPTIN10 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 149/314 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs370353470, COSV100453857; called by muse, mutect2, varscan2
- SEPTIN9 | c.745G>A p.V249I (on ENST00000427177 / NM_001113491.2; = p.V231I on NM_006640.4) | Missense Mutation (SNP) | VAF 213/470 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs766525150; called by muse, mutect2, varscan2
- SERPINA5 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 146/591 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs1437955379; called by muse, mutect2, varscan2
- SERPINC1 | c.1214T>G p.L405R | Missense Mutation (SNP) | VAF 122/265 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62929104; called by muse, mutect2, varscan2
- SETDB1 | c.1408del p.Q470Kfs*18 | Frame Shift Del (DEL) | VAF 188/481 reads (39%) | catalogued as COSV99643465; called by mutect2, pindel, varscan2
- SHANK3 | c.5047G>A p.E1683K | Missense Mutation (SNP) | VAF 287/555 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs1386657338; called by muse, mutect2, varscan2
- SHISA5 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 189/374 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs747718231; called by muse, mutect2, varscan2
- SHLD3 | c.247A>G p.S83G | Missense Mutation (SNP) | VAF 163/350 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.23); catalogued as rs1445736847, COSV51558493; called by muse, mutect2, varscan2
- SHROOM3 | c.3571G>A p.G1191R | Missense Mutation (SNP) | VAF 263/588 reads (45%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.52); catalogued as rs772361218, COSV99935149; called by muse, mutect2, varscan2
- SIGIRR | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 395/879 reads (45%) | catalogued as rs778148546, COSV58985876; called by muse, mutect2, varscan2
- SIK3 | c.3206C>T p.A1069V (on ENST00000445177 / NM_001366686.2; = p.A1027V on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 251/515 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); catalogued as rs373958184; called by muse, mutect2, varscan2
- SIVA1 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 310/1227 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs1165794834; called by muse, mutect2, varscan2
- SLC12A3 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 260/583 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52634402; called by muse, mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 118/256 reads (46%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC1A3 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 162/292 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1301585140; called by muse, varscan2
- SLC22A7 | c.518G>A p.R173H (on ENST00000372585 / NM_153320.2; = p.R171H on NM_006672.3) | Missense Mutation (SNP) | VAF 195/407 reads (48%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.86); catalogued as rs772050503; called by muse, mutect2, varscan2
- SLC25A28 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 159/323 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as rs200683343; called by muse, mutect2, varscan2
- SLC30A3 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 199/423 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as rs749270034, COSV51986908; called by muse, mutect2, varscan2
- SLC35D3 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 307/612 reads (50%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs767981863; called by muse, mutect2, varscan2
- SLC45A4 | c.926C>T p.S309L (on ENST00000517878 / NM_001286646.2; = p.S258L on NM_001080431.2) | Missense Mutation (SNP) | VAF 233/466 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775976981, COSV50176861; called by muse, mutect2, varscan2
- SLC49A3 | c.487del p.A163Pfs*32 | Frame Shift Del (DEL) | VAF 209/480 reads (44%) | catalogued as COSV59140216; called by mutect2, pindel, varscan2
- SLC49A3 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 152/340 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.112); catalogued as rs139449222; called by muse, mutect2, varscan2
- SLC5A5 | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 283/578 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.271); catalogued as rs775925580; called by muse, mutect2, varscan2
- SLC6A12 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 190/458 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs779060532, COSV62885322; called by muse, varscan2
- SLC6A18 | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 424/884 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as COSV57251451; called by muse, mutect2, varscan2
- SLC6A19 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 244/546 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs1367901622; called by muse, varscan2
- SLC9A3 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 301/650 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs752227359, COSV53801524; called by muse, mutect2, varscan2
- SLC9A3 | c.366dup p.I123Hfs*79 | Frame Shift Ins (INS) | VAF 377/865 reads (44%) | catalogued as rs1393384256; called by mutect2, pindel, varscan2
- SLC9C1 | c.29del p.F10Sfs*11 | Frame Shift Del (DEL) | VAF 54/124 reads (44%) | catalogued as rs749004401; called by mutect2, varscan2
- SLITRK2 | c.1717G>A p.G573R | Missense Mutation (SNP) | VAF 27/308 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100157920, COSV59424402; called by muse, mutect2
- SMCHD1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 111/373 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55267300; called by muse, mutect2, varscan2
- SMPD4 | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 250/466 reads (54%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs770954294; called by muse, mutect2, varscan2
- SOAT2 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 257/551 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs988806029; called by muse, mutect2, varscan2
- SORBS2 | c.2132del p.N711Ifs*65 | Frame Shift Del (DEL) | VAF 228/469 reads (49%) | catalogued as rs754977280; called by mutect2, varscan2
- SOWAHD | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 427/428 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV59649383; called by muse, mutect2, varscan2
- SOX13 | c.1010del p.P337Rfs*69 | Frame Shift Del (DEL) | VAF 244/561 reads (43%) | catalogued as rs1362904355; called by mutect2, pindel, varscan2
- SPACA1 | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1225955358; called by muse, mutect2, varscan2
- SPAG11B | c.92C>G p.S31* | Nonsense Mutation (SNP) | VAF 140/720 reads (19%) | catalogued as COSV52500036; called by muse, varscan2
- SPATC1L | c.631G>A p.V211M (on ENST00000291672 / NM_001142854.2; = p.V57M on NM_032261.5) | Missense Mutation (SNP) | VAF 386/807 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs375630459; called by muse, mutect2, varscan2
- SPG11 | c.2849del p.L950Wfs*13 | Frame Shift Del (DEL) | VAF 94/202 reads (47%) | catalogued as CD166713; called by mutect2, varscan2
- SPG21 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 152/337 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374355522; called by muse, mutect2, varscan2
- SRPK1 | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs748936391, COSV100644511; called by muse, mutect2, varscan2
- SRRT | c.2012C>T p.T671M | Missense Mutation (SNP) | VAF 201/391 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs759873478; called by muse, mutect2, varscan2
- SRSF12 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 223/485 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.151); catalogued as rs1172812221, COSV71683781; called by muse, mutect2, varscan2
- SSUH2 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 267/535 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs377451237; called by muse, mutect2, varscan2
- ST8SIA1 | c.943G>A p.V315I | Missense Mutation (SNP) | VAF 230/432 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs752763380; called by muse, mutect2, varscan2
- STAT6 | c.2066T>C p.V689A | Missense Mutation (SNP) | VAF 121/252 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1173595397; called by muse, mutect2, varscan2
- STK36 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 172/365 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs759453372, COSV99831538; called by muse, mutect2, varscan2
- STK36 | c.2330C>A p.P777H | Missense Mutation (SNP) | VAF 123/272 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55330611; called by muse, mutect2, varscan2
- STX4 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 216/453 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs751532816, COSV100572948; called by muse, mutect2, varscan2
- STXBP2 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 174/389 reads (45%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs200855062, COSV55406039; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STYXL2 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 367/737 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.333); catalogued as rs746634720, COSV99609005; called by muse, mutect2, varscan2
- SYCP2L | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs369230080; called by muse, varscan2
- SYT10 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 151/333 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs768366811, COSV57338128; called by muse, mutect2, varscan2
- SYTL1 | c.1118C>T p.T373M (on ENST00000543823; = p.T361M on NM_032872.3) | Missense Mutation (SNP) | VAF 239/486 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs368344700; called by muse, mutect2, varscan2
- TAMALIN | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 146/366 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1382772397; called by muse, mutect2, varscan2
- TBC1D23 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 124/257 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.908); catalogued as rs372446939; called by muse, mutect2, varscan2
- TBC1D9B | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 244/509 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1247176784; called by muse, mutect2, varscan2
- TBR1 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 375/785 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs771817058, COSV67417308; called by muse, mutect2, varscan2
- TBX6 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 308/654 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs776273220, COSV54221806; called by muse, mutect2, varscan2
- TEKT4 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 150/338 reads (44%) | catalogued as rs79674061, COSV54623249, COSV54624137; called by muse, mutect2, varscan2
- TEP1 | c.4963C>T p.R1655* | Nonsense Mutation (SNP) | VAF 338/506 reads (67%) | catalogued as rs762708627, COSV52995160; called by muse, mutect2, varscan2
- TERF1 | c.860C>T p.T287I | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99401514; called by muse, mutect2, varscan2
- TERF2 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 309/627 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.489); catalogued as rs763347805, COSV54746858; called by muse, mutect2, varscan2
- TIAL1 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.028); catalogued as rs758551595, COSV64843554; called by muse, mutect2, varscan2
- TIAM1 | c.3255del p.F1085Lfs*4 | Frame Shift Del (DEL) | VAF 50/134 reads (37%) | catalogued as COSV54540203; called by mutect2, pindel, varscan2
- TLL1 | c.2183dup p.S729Lfs*5 | Frame Shift Ins (INS) | VAF 70/230 reads (30%) | catalogued as rs778685034; called by pindel, varscan2
- TMEM104 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 145/295 reads (49%) | catalogued as rs887041994, COSV59108743; called by muse, mutect2, varscan2
- TMEM174 | c.40A>G p.N14D | Missense Mutation (SNP) | VAF 243/539 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs766942478; called by muse, mutect2, varscan2
- TMEM221 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 136/321 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as rs1051626868; called by muse, mutect2, varscan2
- TMEM94 | c.1970G>A p.R657H | Missense Mutation (SNP) | VAF 258/555 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs747380294; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 40/106 reads (38%) | catalogued as rs770800449; called by mutect2, varscan2
- TMTC3 | c.2356G>T p.D786Y | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs764794677, COSV57125576, COSV57125880; called by muse, mutect2, varscan2
- TNFAIP3 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 243/532 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs150717698; called by muse, mutect2, varscan2
- TNPO2 | c.1433T>C p.L478P | Missense Mutation (SNP) | VAF 274/532 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63509251; called by muse, mutect2, varscan2
- TNRC18 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 244/494 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1386607434; called by muse, mutect2, varscan2
- TNS1 | c.4423G>A p.A1475T | Missense Mutation (SNP) | VAF 124/261 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs369175639, COSV50698031; called by muse, mutect2, varscan2
- TNXB | c.6115G>A p.V2039M (on ENST00000647633; = p.V1792M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 244/526 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs760624007, COSV64489390; called by muse, mutect2, varscan2
- TOR1A | c.668G>T p.R223M | Missense Mutation (SNP) | VAF 182/420 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV61029709; called by muse, mutect2
- TOR4A | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 391/733 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1403123690, COSV62626954; called by muse, mutect2, varscan2
- TRANK1 | c.7882C>T p.R2628C | Missense Mutation (SNP) | VAF 217/461 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs775710241, COSV99042335; called by muse, mutect2, varscan2
- TRIM56 | c.1117C>G p.Q373E | Missense Mutation (SNP) | VAF 265/514 reads (52%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV60160608; called by muse, mutect2, varscan2
- TRIM62 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 308/632 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751839061, COSV52222223; called by muse, mutect2, varscan2
- TRMT9B | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 147/301 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs752838646; called by muse, mutect2, varscan2
- TRPM7 | c.5584C>T p.R1862C | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs753258420, COSV57913087, COSV57916387; called by muse, mutect2, varscan2
- TRRAP | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 95/225 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1353302132, COSV62839636; called by muse, mutect2, varscan2
- TSKS | c.1724del p.G575Efs*? | Frame Shift Del (DEL) | VAF 166/476 reads (35%) | catalogued as COSV55873270, COSV55879896; called by pindel, varscan2
- TSSK1B | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 208/453 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as rs762006295, COSV66815637; called by muse, mutect2, varscan2
- TTC21B | c.1963C>T p.R655W | Missense Mutation (SNP) | VAF 142/291 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138937289; called by muse, mutect2, varscan2
- TTC22 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 409/829 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1210334928; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.43664C>T p.P14555L (on ENST00000591111; = p.P7131L on NM_003319.4) | Missense Mutation (SNP) | VAF 139/356 reads (39%) | PolyPhen benign (0.003); catalogued as rs1485291993, COSV100623183; called by muse, mutect2, varscan2
- TUBA3C | c.1080del p.T361Rfs*18 | Frame Shift Del (DEL) | VAF 175/680 reads (26%) | catalogued as rs750889205; called by mutect2, pindel, varscan2
- UBC | c.493A>G p.I165V | Missense Mutation (SNP) | VAF 193/211 reads (91%) | SIFT deleterious (0.03); PolyPhen benign (0.268); catalogued as rs782274305; called by muse, mutect2, varscan2
- UBQLN3 | c.305G>A p.C102Y | Missense Mutation (SNP) | VAF 212/408 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.224); catalogued as COSV100293214; called by muse, varscan2
- UBR4 | c.6736G>A p.V2246M | Missense Mutation (SNP) | VAF 192/448 reads (43%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.981); catalogued as rs758857582; called by muse, mutect2, varscan2
- UCP1 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 206/459 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs146094549; called by muse, mutect2, varscan2
- UNC80 | c.3701G>A p.R1234H | Missense Mutation (SNP) | VAF 140/305 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1231432263; called by muse, mutect2, varscan2
- URB2 | c.3878C>T p.A1293V | Missense Mutation (SNP) | VAF 155/352 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.293); catalogued as rs772780409; called by muse, mutect2, varscan2
- USH2A | c.14516C>T p.T4839M | Missense Mutation (SNP) | VAF 229/471 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs139065588, COSV56360228, COSV56383574; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- USP15 | c.2278del p.R760Dfs*27 (on ENST00000280377 / NM_001351159.2; = p.R731Dfs*27 on NM_006313.3 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | catalogued as rs749487717; called by mutect2, pindel, varscan2
- USP42 | c.3449G>A p.R1150Q | Missense Mutation (SNP) | VAF 240/512 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.086); catalogued as rs543513683; called by muse, mutect2, varscan2
- USP47 | c.1265A>G p.D422G (on ENST00000399455 / NM_001372095.1; = p.D334G on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as rs375823623; called by muse, mutect2, varscan2
- USP49 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 476/980 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1475392271, COSV51901064; called by muse, mutect2, varscan2
- VCL | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 176/403 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs746095066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VWA5B2 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 130/266 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs1442113047; called by muse, varscan2
- WDFY3 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 164/332 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.018); catalogued as rs867206881; called by muse, mutect2, varscan2
- WDR81 | c.5777G>A p.R1926H (on ENST00000409644 / NM_001163809.2; = p.R875H on NM_152348.4) | Missense Mutation (SNP) | VAF 312/647 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs765640328; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 100/201 reads (50%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- XKR3 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 88/228 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs754227654, COSV58884868; called by muse, mutect2, varscan2
- YLPM1 | c.440dup p.E148* | Frame Shift Ins (INS) | VAF 280/528 reads (53%) | catalogued as rs770407893; called by mutect2, varscan2
- ZAR1L | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 348/1075 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV61525160; called by muse, mutect2, varscan2
- ZBED4 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 192/428 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs371316523; called by muse, mutect2, varscan2
- ZBTB16 | c.378G>T p.Q126H | Missense Mutation (SNP) | VAF 246/459 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100252450; called by muse, mutect2, varscan2
- ZBTB2 | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 172/378 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.153); catalogued as rs915355941; called by muse, mutect2, varscan2
- ZBTB41 | c.714del p.K238Nfs*4 | Frame Shift Del (DEL) | VAF 102/275 reads (37%) | catalogued as COSV100962778; called by mutect2, pindel, varscan2
- ZBTB45 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 254/537 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs771579912; called by muse, mutect2, varscan2
- ZC3H12D | c.967del p.R323Gfs*175 | Frame Shift Del (DEL) | VAF 373/981 reads (38%) | catalogued as rs1374931227; called by mutect2, pindel, varscan2
- ZCWPW1 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 138/318 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs553707769; called by muse, mutect2, varscan2
- ZFR | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 179/353 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.375); catalogued as COSV54053321; called by muse, mutect2, varscan2
- ZFYVE27 | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 204/404 reads (50%) | catalogued as rs1455730995, COSV61747045; called by muse, mutect2, varscan2
- ZIM3 | c.1150del p.I384Sfs*49 | Frame Shift Del (DEL) | VAF 99/244 reads (41%) | catalogued as rs750173990; called by mutect2, pindel, varscan2
- ZMYM6 | c.3158del p.L1053Cfs*10 | Frame Shift Del (DEL) | VAF 50/141 reads (35%) | catalogued as CM1513296; called by mutect2, pindel, varscan2
- ZNF133 | c.195dup p.C66Mfs*37 (on ENST00000316358 / NM_001352454.2; = p.C66Mfs*36 on NM_003434.7 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 112/264 reads (42%) | catalogued as rs753775995; called by mutect2, varscan2
- ZNF208 | c.2054T>A p.V685E | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.196); catalogued as COSV68109927; called by muse, varscan2
- ZNF43 | c.752del p.N251Ifs*28 | Frame Shift Del (DEL) | VAF 44/108 reads (41%) | catalogued as rs753886536; called by mutect2, varscan2
- ZNF445 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 20/600 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as CM142685, COSV101253913; called by muse, mutect2
- ZNF503 | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 366/804 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1177465048, COSV65307409; called by muse, mutect2, varscan2
- ZNF574 | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 294/621 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1336835404; called by muse, mutect2, varscan2
- ZNF626 | c.345del p.G116Dfs*3 | Frame Shift Del (DEL) | VAF 50/129 reads (39%) | catalogued as rs782441698; called by mutect2, pindel, varscan2
- ZNF668 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 387/854 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1342938519; called by muse, mutect2, varscan2
- ZNF701 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs779101161; called by muse, mutect2
- ZNF746 | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 304/614 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.1); catalogued as rs765996641; called by muse, mutect2, varscan2
- ZNF750 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 263/545 reads (48%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as rs371042619, COSV53960694; called by muse, mutect2, varscan2
- ZNF823 | c.631G>A p.E211K (on ENST00000341191 / NM_001297610.2; = p.E167K on NM_017507.2) | Missense Mutation (SNP) | VAF 172/342 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs747534988; called by muse, mutect2, varscan2
- ZNRF3 | c.631C>T p.R211* (on ENST00000544604 / NM_001206998.2; = p.R111* on NM_032173.3) | Nonsense Mutation (SNP) | VAF 138/281 reads (49%) | catalogued as COSV60434667; called by muse, varscan2
- ZSCAN22 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 265/604 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs187661233; called by muse, mutect2, varscan2
- A2M | c.3147del p.F1049Lfs*43 | Frame Shift Del (DEL) | VAF 143/364 reads (39%) | called by mutect2, pindel, varscan2
- AACS | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 72/766 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2
- AC011462.1 | c.1376A>C p.E459A | Missense Mutation (SNP) | VAF 261/510 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AC092143.1 | c.1858del p.L620Sfs*12 | Frame Shift Del (DEL) | VAF 256/488 reads (52%) | called by mutect2, varscan2
- ACE | c.1235C>G p.A412G | Missense Mutation (SNP) | VAF 208/458 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- ACTR8 | c.654del p.K218Nfs*7 | Frame Shift Del (DEL) | VAF 119/298 reads (40%) | called by mutect2, pindel, varscan2
- ADAMTS9 | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 195/439 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADCY3 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 387/696 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADGRG1 | c.1541G>A p.G514D | Missense Mutation (SNP) | VAF 175/341 reads (51%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ADGRL2 | c.881A>G p.Y294C | Missense Mutation (SNP) | VAF 200/370 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRL4 | c.1586del p.L529Cfs*11 | Frame Shift Del (DEL) | VAF 164/439 reads (37%) | called by pindel, varscan2
- ADGRV1 | c.2419A>G p.K807E | Missense Mutation (SNP) | VAF 146/312 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADORA3 | c.535T>C p.Y179H | Missense Mutation (SNP) | VAF 199/428 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADRA2C | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 307/630 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADRM1 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 206/427 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGAP2 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 441/887 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGO4 | c.2500G>A p.G834R | Missense Mutation (SNP) | VAF 108/258 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- AHNAK2 | c.2948A>G p.D983G | Missense Mutation (SNP) | VAF 379/1409 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- AKAP13 | c.6075G>C p.M2025I (on ENST00000394518 / NM_007200.5; = p.M2029I on NM_006738.6) | Missense Mutation (SNP) | VAF 158/341 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- AKR7A2 | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 204/410 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AMOTL1 | c.1396G>T p.A466S | Missense Mutation (SNP) | VAF 134/299 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ANAPC2 | c.650A>G p.Q217R | Missense Mutation (SNP) | VAF 285/631 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANK2 | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 218/437 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ANKRD17 | c.6179C>A p.P2060H | Missense Mutation (SNP) | VAF 210/429 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ANKRD36B | c.1452_1454del p.K485del | In Frame Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- ANKRD65 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 83/140 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ANOS1 | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 234/234 reads (100%) | SIFT tolerated (0.7); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- AP3B1 | c.2769del p.K923Nfs*4 | Frame Shift Del (DEL) | VAF 38/76 reads (50%) | called by mutect2, varscan2
- AP3B2 | c.2989G>T p.G997C (on ENST00000261722; = p.G991C on NM_004644.5) | Missense Mutation (SNP) | VAF 171/345 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APBB1IP | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APOBEC4 | c.781T>C p.Y261H | Missense Mutation (SNP) | VAF 194/360 reads (54%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARAF | c.23del p.P8Lfs*26 | Frame Shift Del (DEL) | VAF 249/345 reads (72%) | called by mutect2, pindel, varscan2
- ARHGAP28 | c.479T>C p.M160T (on ENST00000383472 / NM_001366230.1; = p.M1? on NM_001010000.3) | Missense Mutation (SNP) | VAF 157/466 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ARHGAP28 | c.715A>G p.S239G (on ENST00000383472 / NM_001366230.1; = p.S80G on NM_001010000.3) | Missense Mutation (SNP) | VAF 126/457 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ARHGAP31 | c.3089C>A p.P1030H | Missense Mutation (SNP) | VAF 220/511 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- ARMC4 | c.736dup p.E246Gfs*13 | Frame Shift Ins (INS) | VAF 184/447 reads (41%) | called by mutect2, pindel, varscan2
- ASPDH | c.389del p.G130Afs*80 | Frame Shift Del (DEL) | VAF 260/693 reads (38%) | called by mutect2, pindel, varscan2
- ASPM | c.9292dup p.R3098Kfs*26 | Frame Shift Ins (INS) | VAF 49/121 reads (40%) | called by mutect2, pindel, varscan2
- ASTL | c.394T>C p.C132R | Missense Mutation (SNP) | VAF 245/484 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASTN2 | c.522C>G p.H174Q | Missense Mutation (SNP) | VAF 201/471 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ATAD2B | c.1328C>A p.P443H | Missense Mutation (SNP) | VAF 135/297 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATL1 | c.1112T>C p.M371T | Missense Mutation (SNP) | VAF 126/487 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AUH | c.1001del p.P334Lfs*13 | Frame Shift Del (DEL) | VAF 22/91 reads (24%) | called by mutect2, pindel, varscan2
- AUTS2 | c.3580T>C p.Y1194H | Missense Mutation (SNP) | VAF 342/691 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AXIN2 | c.1610A>G p.Q537R | Missense Mutation (SNP) | VAF 41/722 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2
- B3GLCT | c.238del p.S80Afs*3 | Frame Shift Del (DEL) | VAF 66/250 reads (26%) | called by mutect2, varscan2
- B3GNTL1 | c.157_160del p.V53Sfs*18 | Frame Shift Del (DEL) | VAF 145/343 reads (42%) | called by mutect2, pindel, varscan2
- BACE1 | c.1499T>G p.L500R | Missense Mutation (SNP) | VAF 132/291 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCL9 | c.1027dup p.T343Nfs*34 | Frame Shift Ins (INS) | VAF 303/734 reads (41%) | called by mutect2, pindel, varscan2
- BCLAF1 | c.767del p.N256Ifs*82 | Frame Shift Del (DEL) | VAF 110/508 reads (22%) | called by mutect2, pindel, varscan2
- BICRA | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 402/843 reads (48%) | called by muse, mutect2, varscan2
- BMP1 | c.1253G>A p.S418N | Missense Mutation (SNP) | VAF 182/388 reads (47%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- BMPR2 | c.1028del p.N343Mfs*14 | Frame Shift Del (DEL) | VAF 154/369 reads (42%) | called by mutect2, pindel, varscan2
- BOD1L1 | c.5549A>G p.D1850G | Missense Mutation (SNP) | VAF 274/527 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BOP1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 405/852 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BPTF | c.4432A>G p.K1478E | Missense Mutation (SNP) | VAF 145/290 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- C11orf96 | c.1139A>T p.E380V (on ENST00000339446; = p.E67V on NM_001145033.2) | Missense Mutation (SNP) | VAF 219/442 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, varscan2
- C19orf81 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 183/364 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- C1GALT1 | c.29dup p.L10Ffs*19 | Frame Shift Ins (INS) | VAF 48/155 reads (31%) | called by mutect2, pindel, varscan2
- C1QL1 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 255/460 reads (55%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- C1S | c.1909G>T p.A637S | Missense Mutation (SNP) | VAF 207/428 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- CACNA1E | c.3016del p.L1006* | Frame Shift Del (DEL) | VAF 276/710 reads (39%) | called by mutect2, pindel, varscan2
- CADPS | c.231del p.L78Cfs*20 | Frame Shift Del (DEL) | VAF 132/250 reads (53%) | called by mutect2, varscan2
- CALD1 | c.1618C>T p.R540C (on ENST00000361675 / NM_033138.4; = p.R285C on NM_004342.7) | Missense Mutation (SNP) | VAF 272/497 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- CARD14 | c.2443C>T p.P815S | Missense Mutation (SNP) | VAF 304/609 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- CATSPER1 | c.1036A>T p.T346S | Missense Mutation (SNP) | VAF 255/519 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBX8 | c.956del p.G319Afs*37 | Frame Shift Del (DEL) | VAF 211/480 reads (44%) | called by mutect2, varscan2
- CC2D2A | c.181del p.Q61Rfs*13 (on ENST00000424120 / NM_001378615.1; = p.P96Qfs*52 on NM_020785.2) | Frame Shift Del (DEL) | VAF 184/399 reads (46%) | called by mutect2, pindel, varscan2
- CCDC110 | c.928_929del p.K310Efs*28 | Frame Shift Del (DEL) | VAF 68/150 reads (45%) | called by mutect2, pindel, varscan2
- CCDC125 | c.68T>C p.M23T | Missense Mutation (SNP) | VAF 265/542 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC149 | c.1303G>A p.G435R (on ENST00000635206 / NM_001330643.2; = p.G424R on NM_173463.5) | Missense Mutation (SNP) | VAF 243/496 reads (49%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC177 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 382/1569 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC33 | c.385A>G p.K129E | Missense Mutation (SNP) | VAF 42/458 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- CCM2 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 198/424 reads (47%) | called by muse, mutect2, varscan2
- CCT3 | c.1436del p.G479Vfs*2 | Frame Shift Del (DEL) | VAF 75/241 reads (31%) | called by mutect2, pindel, varscan2
- CD276 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 78/732 reads (11%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- CDK18 | c.1170del p.T391Qfs*8 (on ENST00000506784 / NM_212503.3; = p.T361Qfs*8 on NM_002596.4) | Frame Shift Del (DEL) | VAF 226/601 reads (38%) | called by mutect2, pindel, varscan2
- CDK7 | c.597dup p.G200Wfs*21 | Frame Shift Ins (INS) | VAF 222/537 reads (41%) | called by mutect2, pindel, varscan2
- CDT1 | c.853del p.Q285Sfs*33 | Frame Shift Del (DEL) | VAF 251/625 reads (40%) | called by mutect2, pindel, varscan2
- CELSR1 | c.2450A>G p.D817G | Missense Mutation (SNP) | VAF 273/548 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELSR2 | c.2691del p.M898Cfs*10 | Frame Shift Del (DEL) | VAF 188/536 reads (35%) | called by mutect2, pindel, varscan2
- CELSR2 | c.8582G>A p.C2861Y | Missense Mutation (SNP) | VAF 62/627 reads (10%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.015); called by muse, mutect2
- CELSR3 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 351/783 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP126 | c.2473A>G p.T825A | Missense Mutation (SNP) | VAF 80/183 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- CEP152 | c.2375G>A p.G792D | Missense Mutation (SNP) | VAF 166/371 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CEP170B | c.2323del p.Q775Rfs*49 (on ENST00000453495; = p.Q704Rfs*49 on NM_015005.3) | Frame Shift Del (DEL) | VAF 391/1592 reads (25%) | called by mutect2, varscan2
- CEP250 | c.3298A>G p.S1100G | Missense Mutation (SNP) | VAF 127/285 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP157 | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 349/670 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- CFAP65 | c.392dup p.K133Efs*14 (on ENST00000341552 / NM_194302.4; = p.K68Efs*14 on NM_152389.4) | Frame Shift Ins (INS) | VAF 125/341 reads (37%) | called by mutect2, pindel, varscan2
- CHMP4B | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 247/495 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- CHUK | c.1748G>A p.S583N | Missense Mutation (SNP) | VAF 11/314 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- CILP2 | c.124T>C p.Y42H | Missense Mutation (SNP) | VAF 258/530 reads (49%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLEC12A | c.733del p.R245Efs*2 | Frame Shift Del (DEL) | VAF 43/101 reads (43%) | called by mutect2, pindel, varscan2
- CLVS2 | c.863T>C p.V288A | Missense Mutation (SNP) | VAF 126/247 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- CMYA5 | c.2066G>A p.C689Y | Missense Mutation (SNP) | VAF 187/407 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNNM1 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 241/509 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNOT1 | c.509_511del p.E170del | In Frame Del (DEL) | VAF 136/302 reads (45%) | called by pindel, varscan2
- CNOT4 | c.2063del p.P688Qfs*94 (on ENST00000541284 / NM_001190850.1; = p.P614Qfs*? on NM_013316.4) | Frame Shift Del (DEL) | VAF 267/550 reads (49%) | called by mutect2, pindel, varscan2
- CNTLN | c.2806C>T p.H936Y | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN1 | c.2647del p.A883Pfs*13 | Frame Shift Del (DEL) | VAF 151/383 reads (39%) | called by mutect2, pindel, varscan2
- COIL | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 159/381 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL22A1 | c.3585del p.P1197Qfs*231 | Frame Shift Del (DEL) | VAF 142/384 reads (37%) | called by mutect2, pindel, varscan2
- COL6A6 | c.994del p.V332Cfs*8 | Frame Shift Del (DEL) | VAF 198/546 reads (36%) | called by mutect2, pindel, varscan2
- COMMD4 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 264/507 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- COPB2 | c.1266del p.K422Nfs*23 | Frame Shift Del (DEL) | VAF 22/49 reads (45%) | called by mutect2, varscan2
- CORO1C | c.759G>A p.M253I | Missense Mutation (SNP) | VAF 31/270 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CORO7 | c.1600C>G p.P534A | Missense Mutation (SNP) | VAF 230/542 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CPO | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 86/219 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CREBBP | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 250/731 reads (34%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- CRIM1 | c.2567del p.P856Lfs*67 | Frame Shift Del (DEL) | VAF 254/636 reads (40%) | called by mutect2, pindel, varscan2
- CRMP1 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 197/420 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- CRYBG2 | c.4583G>T p.R1528L | Missense Mutation (SNP) | VAF 121/263 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- CSNK1G2 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 279/633 reads (44%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUX1 | c.1373C>T p.A458V (on ENST00000437600 / NM_181500.4; = p.A460V on NM_001913.5) | Missense Mutation (SNP) | VAF 159/313 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CWC25 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 184/438 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DACH2 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 171/171 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DAPK1 | c.2591T>C p.V864A | Missense Mutation (SNP) | VAF 145/308 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DCC | c.3089T>C p.V1030A | Missense Mutation (SNP) | VAF 186/310 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.279); called by muse, mutect2
- DCST1 | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 127/291 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- DDIT4 | c.371T>C p.V124A | Missense Mutation (SNP) | VAF 386/759 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX4 | c.746del p.P249Lfs*18 | Frame Shift Del (DEL) | VAF 120/314 reads (38%) | called by mutect2, pindel, varscan2
- DERA | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 71/126 reads (56%) | SIFT tolerated (0.68); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- DGKI | c.2517G>T p.L839F | Missense Mutation (SNP) | VAF 77/134 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- DIAPH3 | c.1826C>A p.P609H (on ENST00000400324 / NM_001042517.2; = p.P346H on NM_030932.3) | Missense Mutation (SNP) | VAF 261/265 reads (98%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- DNAJC14 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 192/405 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DTX1 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 292/568 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUSP2 | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 452/952 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- DYNC1H1 | c.6219del p.F2073Lfs*21 | Frame Shift Del (DEL) | VAF 315/556 reads (57%) | called by mutect2, pindel, varscan2
- DYNC2H1 | c.1070G>A p.C357Y | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ECHDC2 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 215/512 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- EFL1 | c.697_699del p.V233del | In Frame Del (DEL) | VAF 111/264 reads (42%) | called by pindel, varscan2
- EHBP1L1 | c.3022dup p.A1008Gfs*15 | Frame Shift Ins (INS) | VAF 351/854 reads (41%) | called by mutect2, pindel, varscan2
- EPAS1 | c.1526C>T p.T509I | Missense Mutation (SNP) | VAF 117/316 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EPB41L3 | c.1291G>T p.E431* | Nonsense Mutation (SNP) | VAF 315/514 reads (61%) | called by mutect2, varscan2
- EPHA6 | c.1365del p.D456Ifs*6 | Frame Shift Del (DEL) | VAF 206/503 reads (41%) | called by mutect2, pindel, varscan2
- EPHA6 | c.3145G>T p.G1049C | Missense Mutation (SNP) | VAF 90/226 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- EPM2AIP1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 254/512 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERC2 | c.1528del p.T510Qfs*21 | Frame Shift Del (DEL) | VAF 160/335 reads (48%) | called by mutect2, pindel, varscan2
- ERCC3 | c.1944dup p.G649Rfs*38 | Frame Shift Ins (INS) | VAF 139/362 reads (38%) | called by pindel, varscan2
- ERF | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 320/732 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); called by muse, mutect2
- ERVFRD-1 | c.1315T>C p.C439R | Missense Mutation (SNP) | VAF 155/371 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERVMER34-1 | c.62del p.L21Qfs*18 | Frame Shift Del (DEL) | VAF 152/398 reads (38%) | called by mutect2, pindel, varscan2
- EVA1C | c.420del p.F140Lfs*24 | Frame Shift Del (DEL) | VAF 236/578 reads (41%) | called by mutect2, pindel, varscan2
- EVA1C | c.494dup p.N165Kfs*6 | Frame Shift Ins (INS) | VAF 119/304 reads (39%) | called by mutect2, pindel, varscan2
- EVC | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 137/254 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, varscan2
- EZH1 | c.1792A>G p.K598E | Missense Mutation (SNP) | VAF 186/406 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FAM111B | c.1398G>T p.W466C | Missense Mutation (SNP) | VAF 159/306 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM133A | c.271del p.R91Efs*67 | Frame Shift Del (DEL) | VAF 33/45 reads (73%) | called by mutect2, pindel, varscan2
- FAM160A2 | c.896T>G p.L299R | Missense Mutation (SNP) | VAF 190/367 reads (52%) | SIFT tolerated (0.86); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- FAM9A | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 263/264 reads (100%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- FAP | c.29G>C p.G10A | Missense Mutation (SNP) | VAF 153/328 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- FAT4 | c.12866C>T p.A4289V | Missense Mutation (SNP) | VAF 129/240 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- FBN2 | c.826G>T p.D276Y | Missense Mutation (SNP) | VAF 156/310 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBN3 | c.1180G>T p.G394C | Missense Mutation (SNP) | VAF 183/358 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FER1L6 | c.3251A>G p.Y1084C | Missense Mutation (SNP) | VAF 242/492 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGF20 | c.190C>A p.L64M | Missense Mutation (SNP) | VAF 289/583 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.263); called by muse, varscan2
- FIGN | c.210dup p.Y71Ifs*35 | Frame Shift Ins (INS) | VAF 166/384 reads (43%) | called by mutect2, varscan2
- FKBP8 | c.997C>A p.L333M (on ENST00000222308 / NM_001308373.2; = p.L334M on NM_012181.5) | Missense Mutation (SNP) | VAF 165/349 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- FKBP9 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 427/964 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FMN1 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 151/337 reads (45%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FMN2 | c.3110C>A p.P1037H | Missense Mutation (SNP) | VAF 60/399 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FMO2 | c.291del p.K97Nfs*5 | Frame Shift Del (DEL) | VAF 52/134 reads (39%) | called by mutect2, pindel, varscan2
- FOXD4L6 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 341/1135 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); called by muse, varscan2
- FOXM1 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 175/398 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FREM2 | c.3391A>T p.I1131F | Missense Mutation (SNP) | VAF 318/507 reads (63%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- FRY | c.2462T>C p.L821S | Missense Mutation (SNP) | VAF 204/620 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FRYL | c.392T>C p.L131S | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- GALNS | c.296C>G p.T99S | Missense Mutation (SNP) | VAF 282/563 reads (50%) | SIFT tolerated (0.3); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GBP6 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 180/364 reads (49%) | called by muse, mutect2, varscan2
- GEMIN5 | c.1264del p.W422Gfs*4 | Frame Shift Del (DEL) | VAF 136/390 reads (35%) | called by pindel, varscan2
- GFPT2 | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 252/517 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GGT7 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 362/703 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- GNAS | c.1297del p.A433Qfs*257 | Frame Shift Del (DEL) | VAF 514/1272 reads (40%) | called by mutect2, pindel, varscan2
- GPATCH8 | c.564dup p.Q189Tfs*10 | Frame Shift Ins (INS) | VAF 137/354 reads (39%) | called by mutect2, pindel, varscan2
- GPR143 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 340/343 reads (99%) | SIFT tolerated (0.61); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GPR162 | c.909del p.W304Gfs*82 (on ENST00000311268 / NM_019858.2; = p.W20Gfs*82 on NM_014449.2) | Frame Shift Del (DEL) | VAF 199/502 reads (40%) | called by mutect2, pindel, varscan2
- GPR4 | c.20A>G p.E7G | Missense Mutation (SNP) | VAF 181/372 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- GPR45 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 341/728 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- GRIN1 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 369/751 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- GRM3 | c.1633A>G p.T545A | Missense Mutation (SNP) | VAF 218/447 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- GRM8 | c.1730T>C p.L577S | Missense Mutation (SNP) | VAF 242/510 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- GTF3C4 | c.830C>A p.A277D | Missense Mutation (SNP) | VAF 187/382 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HAP1 | c.1981G>T p.A661S (on ENST00000310778 / NM_001367460.1; = p.A609S on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 235/490 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- HCN1 | c.1534dup p.M512Nfs*17 | Frame Shift Ins (INS) | VAF 98/224 reads (44%) | called by mutect2, varscan2
- HDLBP | c.2749G>T p.V917F | Missense Mutation (SNP) | VAF 125/237 reads (53%) | SIFT tolerated (0.72); PolyPhen benign (0.308); called by muse, mutect2, varscan2
700 further variants in this file (334 protein-altering or splice-affecting, 323 silent, 43 other) are not listed here.
